Somatic mutation profile of tumor specimen TCGA-D3-A51H-06A (aliquot TCGA-D3-A51H-06A-12D-A25O-08) from TCGA case TCGA-D3-A51H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.6 years (22,881 days).
Specimen TCGA-D3-A51H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 983c023a-6208-47c5-bed5-20b961da8a98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51H-10A (Blood Derived Normal), aliquot TCGA-D3-A51H-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0abe7ced-f0cb-4102-8725-64d7ca23caa0

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP36 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.994); catalogued as COSV52266219; called by muse, mutect2
- BEST3 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV58301006; called by muse, mutect2, varscan2
- CFAP47 | c.4808G>A p.G1603E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57972318; called by muse, mutect2
- KIAA1549L | c.2678A>G p.Y893C (on ENST00000321505; = p.Y1190C on NM_012194.3) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55772798; called by muse, mutect2
- LRRC4C | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as rs868544201, COSV53423990; called by muse, mutect2
- MAGEC1 | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53571884, COSV99596794; called by muse, mutect2, varscan2
- OPN1SW | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV50821610; called by mutect2, varscan2
- OR8H2 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1352684660, COSV57943403; called by muse, mutect2
- PIGK | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV63649819; called by muse, mutect2
- PPP2R1A | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs1404808367, COSV59043990; called by muse, mutect2, varscan2
- PSG11 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 6/144 reads (4%) | catalogued as COSV60454947; called by muse, mutect2
- UNC93A | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV57808255; called by muse, mutect2
- DNAH5 | c.6157C>T p.L2053= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV54220899; called by muse, mutect2
- EPHA1 | c.1440C>T p.T480= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV51970846; called by muse, mutect2
- GABRB2 | c.762C>T p.I254= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1372377153, COSV50909317; called by muse, mutect2
- MAGEC1 | c.2583C>T p.S861= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53571894; called by muse, mutect2
- NLRP8 | c.18A>G p.P6= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV52586516; called by muse, mutect2
- NUP205 | c.1107C>T p.F369= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1174862503, COSV53658288; called by muse, mutect2
- PCDHA8 | c.564G>A p.E188= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs781972042, COSV65334890; called by muse, mutect2
